Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5771, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5771-01A (Primary Tumor).

CGA-CH-5771

Diagnosis

1. Poorly differentiated, multifocal, bilateral adenocarcinoma of the prostate, limited to the organ (Gleason 4+3=7; tertiary grade 5). Gleason 4: 60%, Gleason 5: 10%. Maximum tumor diameter 1.6 cm. Multifocal tumor involvement of perineural sheaths.

Tumor-free surgical preparation margin.

Additional foci of a prostatic intraepithelial neoplasia (HGPIN) and signs of myoglandular prostatic hyperplasia. Urothelium of prostatic urethra without dysplasia.

Tumor-free, regular seminal vesicles and seminal ducts.

2. A tumor-free lymph node on the right (0/1).

3. A tumor-free lymph node on the left (0/1).

Tumor classification

pT2c, max. tumor diameter 16 mm, Gleason 4+3=7 (Gleason 4: 60%, tertiary grade 5: 10%), R0, pN0 (0/2).

Remark

In the prior punch biopsies, Gleason 4 and Gleason 5 patterns were also identified.

Additional immunohistochemical studies were initiated to clarify the vascular status. The results will be presented in a follow-up report.

Follow-up report

Immunohistology: CD31, D2-40

In the meantime, additional immunohistological studies were carried out to establish whether there was invasion of blood or lymph vessels. These investigations did not show any evidence that the tumor had infiltrated the blood or lymph vessels.

Final tumor classification:

pT2c, max. tumor diameter 16 mm. Gleason 4+3=7 (Gleason 4: 60%, tertiary grade 5: 10%), L0, V0, R0, pN0 (0/2).

Source: NCI Genomic Data Commons file 6e056d97-50b0-463b-b72a-1c03104f56b8 (TCGA-CH-5771.7C775A61-67F6-42A1-84E6-5CF8CD66A038.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).